Somatic mutation profile of tumor specimen 0DTYB4 from CCDI case PBCJYV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Lip, NOS; Age at diagnosis: 6.6 years (2,411 days).
Specimen 0DTYB4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 662f7542-57d5-4968-9e0d-a8273017ee86.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTYAU (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7bcad336-618d-4d30-a950-bc4cf8b4b6fc

The open-access MAF lists 11 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 5, Missense Mutation 4, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 48/392 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- CALCOCO1 | c.1192G>A p.G398S | Missense Mutation (SNP) | VAF 54/492 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs772519584, COSV50412321; called by muse, varscan2
- KCNA10 | c.403C>T p.R135W | Missense Mutation (SNP) | VAF 55/348 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755048620, COSV63904386; called by muse, varscan2
- OLFML3 | c.476C>T p.T159I | Missense Mutation (SNP) | VAF 54/430 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.886); called by muse, varscan2
- CLVS1 | c.504C>T p.V168= | Silent (SNP) | VAF 76/578 reads (13%) | catalogued as COSV100370131; called by muse, varscan2
- FLG | c.1635T>C p.H545= | Silent (SNP) | VAF 33/220 reads (15%) | catalogued as rs753421108; called by muse, varscan2
- ATP5F1A | c.140-80A>C | Intron (SNP) | VAF 13/92 reads (14%) | called by muse, varscan2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 16/104 reads (15%) | called by muse, varscan2
- CALCOCO2 | c.825+77T>A | Intron (SNP) | VAF 16/104 reads (15%) | called by muse, varscan2
- CEP295 | c.5948-63T>G | Intron (SNP) | VAF 6/34 reads (18%) | called by muse, varscan2
- LARP4 | c.1334+88A>C | Intron (SNP) | VAF 7/60 reads (12%) | called by muse, varscan2
